Somatic mutation profile of tumor specimen TCGA-DX-AB2E-01A (aliquot TCGA-DX-AB2E-01A-11D-A38Z-09) from TCGA case TCGA-DX-AB2E, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 60.6 years (22,117 days).
Specimen TCGA-DX-AB2E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc3385e1-30f0-4522-8707-de19de22e00a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2E-10A (Blood Derived Normal), aliquot TCGA-DX-AB2E-10A-01D-A38Z-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdbc4cec-14de-461d-9ff5-f2dd0a564380

The open-access MAF lists 1,079 somatic variants for this specimen: 674 protein-altering or splice-affecting, 379 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 597, Silent 379, Nonsense Mutation 35, Splice Site 16, Frame Shift Del 12, Intron 11, Splice Region 10, RNA 6, 5'Flank 4, 3'Flank 3, 3'UTR 1, Nonstop Mutation 1.

Variants (750 of 1,079; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLN3 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 30/62 reads (48%) | catalogued as rs1555469477, COSV100112524; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.11653C>T p.R3885* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | catalogued as rs756032160, COSV54218449, COSV99449428; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 32/56 reads (57%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by muse, mutect2, varscan2
- LAMA4 | c.2849C>T p.P950L (on ENST00000230538 / NM_001105206.3; = p.P943L on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs387907365, CM073173, COSV100038321, COSV100039392; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 53/110 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 13/15 reads (87%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99256102; called by muse, mutect2, varscan2
- A2M | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV100588659; called by muse, mutect2, varscan2
- ABCA13 | c.5522G>T p.C1841F | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101330032, COSV101330109; called by mutect2, varscan2
- ABCA7 | c.2271C>T p.G757= | Splice Region (SNP) | VAF 101/147 reads (69%) | catalogued as COSV99565721; called by muse, mutect2, varscan2
- ABCB5 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as rs757262393, COSV101295915; called by muse, mutect2, varscan2
- ABCC8 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 19/35 reads (54%) | catalogued as COSV100217225; called by muse, mutect2, varscan2
- ABCC8 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100217228; called by muse, mutect2, varscan2
- ABCC9 | c.3908C>T p.P1303L | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99685626; called by muse, mutect2, varscan2
- ABCD4 | c.1448C>T p.P483L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV100084118, COSV100084470; called by muse, mutect2, varscan2
- ABCG1 | c.1835C>T p.S612F | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV100494160; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ACTN3 | c.946G>A p.G316S | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV72207578; called by muse, mutect2, varscan2
- ADAD1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs78087673, COSV99635305; called by muse, mutect2, varscan2
- ADAMTS18 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 24/57 reads (42%) | catalogued as COSV51408683; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1155G>A p.W385* | Nonsense Mutation (SNP) | VAF 10/17 reads (59%) | catalogued as COSV99442628; called by muse, mutect2, varscan2
- ADCK1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as COSV99451667; called by muse, mutect2, varscan2
- ADCY10 | c.3064C>T p.P1022S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100896834; called by muse, mutect2, varscan2
- ADCY8 | c.1265G>A p.G422E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53917263, COSV53935546; called by muse, mutect2, varscan2
- ADD2 | c.1936G>A p.G646R | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.116); catalogued as rs560319503, COSV100035566; called by muse, mutect2, varscan2
- ADGRB3 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65408448; called by muse, mutect2, varscan2
- ADGRB3 | c.4504G>A p.E1502K | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV53245945, COSV99484953; called by muse, mutect2, varscan2
- ADGRF2 | c.2014G>A p.D672N (on ENST00000296862 / NM_001368115.2; = p.D604N on NM_153839.7) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs144129468, COSV57286912; called by muse, mutect2, varscan2
- ADGRG4 | c.4877C>T p.S1626F | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99794690; called by muse, mutect2, varscan2
- ADH1C | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV101565182; called by muse, mutect2, varscan2
- ADH4 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV99644177; called by muse, mutect2, varscan2
- ADH7 | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 28/45 reads (62%) | catalogued as COSV99265052, COSV99265221; called by muse, mutect2, varscan2
- ADNP2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100080821; called by muse, mutect2, varscan2
- AGXT2 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.006); catalogued as COSV99183748; called by muse, mutect2, varscan2
- AKAP8 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 38/53 reads (72%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV99511904; called by muse, mutect2, varscan2
- AKNAD1 | c.1826G>A p.R609K | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV100645513; called by muse, mutect2
- AL592490.1 | c.659A>G p.E220G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69425891; called by muse, mutect2
- ALAS1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | catalogued as COSV100050320; called by muse, mutect2, varscan2
- ALG11 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV101584287; called by muse, mutect2, varscan2
- AMER3 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs374958959, COSV58470765; called by muse, mutect2, varscan2
- AMY1C | c.1096G>A p.G366R | Missense Mutation (SNP) | VAF 50/459 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs763143846, COSV100915192; called by muse, mutect2, varscan2
- AMY1C | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 51/582 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as COSV100915189; called by muse, mutect2
- ANK3 | c.9424C>T p.P3142S | Missense Mutation (SNP) | VAF 63/89 reads (71%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.063); catalogued as COSV99779800; called by muse, mutect2, varscan2
- ANK3 | c.7766C>T p.T2589I | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as rs562676999, COSV99779802; called by muse, varscan2
- ANK3 | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 38/56 reads (68%) | catalogued as COSV99779807; called by muse, mutect2, varscan2
- ANXA3 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1040398990, COSV99363699; called by muse, mutect2, varscan2
- AP3B2 | c.3236T>A p.V1079E (on ENST00000261722; = p.V1073E on NM_004644.5) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV99916464; called by muse, mutect2, varscan2
- AP3B2 | c.3235G>A p.V1079I (on ENST00000261722; = p.V1073I on NM_004644.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.156); catalogued as rs201769141, COSV99916466; called by muse, mutect2, varscan2
- APCS | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV54817475, COSV99661309; called by muse, mutect2
- APOB | c.4546G>A p.G1516R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99265528; called by muse, mutect2, varscan2
- APOBEC3B | c.150G>A p.W50* | Nonsense Mutation (SNP) | VAF 19/85 reads (22%) | catalogued as COSV100213754; called by muse, mutect2, varscan2
- APOBEC3B | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV59840823; called by muse, mutect2, varscan2
- APOBEC3G | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV101349072, COSV68470170; called by muse, mutect2, varscan2
- APRT | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV99243165; called by muse, mutect2, varscan2
- ARHGAP36 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV99357656; called by muse, mutect2, varscan2
- ARHGAP5 | c.3780T>A p.F1260L (on ENST00000345122 / NM_001030055.2; = p.F1259L on NM_001173.3) | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV100565372; called by muse, mutect2, varscan2
- ARMC4 | c.1534-1G>A p.X512_splice | Splice Site (SNP) | VAF 19/54 reads (35%) | catalogued as COSV100536748, COSV59474544; called by muse, mutect2, varscan2
- ARPP21 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 53/129 reads (41%) | catalogued as COSV51792987; called by muse, mutect2, varscan2
- ARPP21 | c.2260C>T p.Q754* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV51797996; called by muse, mutect2, varscan2
- ASB10 | c.742G>A p.G248S (on ENST00000420175 / NM_001142459.2; = p.G233S on NM_080871.4) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1415673633, COSV99318581; called by muse, mutect2, varscan2
- ASPH | c.559C>T p.L187F | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.022); catalogued as COSV100727545; called by muse, mutect2, varscan2
- ATAD2 | c.2069C>T p.S690F | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99784654; called by muse, mutect2, varscan2
- ATP13A4 | c.1442A>G p.N481S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99794471; called by muse, mutect2, varscan2
- ATP1A2 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.566); catalogued as COSV100767823; called by muse, mutect2, varscan2
- ATP5F1B | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.049); catalogued as rs1157350251, COSV99466080; called by muse, mutect2, varscan2
- ATP8A1 | c.1129G>A p.D377N | Missense Mutation (SNP) | VAF 41/65 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100046102, COSV52540882; called by muse, mutect2, varscan2
- AXDND1 | c.811C>T p.R271* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as rs149782250; called by muse, mutect2, varscan2
- BACH2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57610512, COSV57611676; called by muse, mutect2, varscan2
- BAHCC1 | c.4453C>T p.R1485W | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311616; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.794); catalogued as rs1329381327, COSV100260098, COSV57637560; called by muse, mutect2, varscan2
- BAIAP2L2 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.554); catalogued as COSV100260105; called by muse, mutect2, varscan2
- BAIAP3 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs781169474, COSV100181451; called by muse, mutect2, varscan2
- BAZ2A | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs752541395, COSV99466065; called by muse, mutect2, varscan2
- BBOX1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV54191696; called by muse, mutect2
- BCAR1 | c.916T>C p.Y306H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1482973176, COSV99366601; called by muse, mutect2, varscan2
- BCAR1 | c.915C>T p.V305= | Splice Region (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99366609; called by muse, mutect2, varscan2
- BCL6 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs755666072, COSV99215669; called by muse, mutect2, varscan2
- BCO1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99257934; called by muse, mutect2
- BECN1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100162099, COSV59311858; called by muse, mutect2, varscan2
- BIN2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99909377; called by muse, mutect2, varscan2
- BPIFB4 | c.700C>T p.L234F | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100971515; called by muse, mutect2, varscan2
- C10orf120 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.605); catalogued as rs756538058, COSV100271618; called by muse, mutect2, varscan2
- C1QB | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs3211003, COSV59245520; called by muse, mutect2, varscan2
- C1orf87 | c.484-1G>A p.X162_splice | Splice Site (SNP) | VAF 20/76 reads (26%) | catalogued as rs769100244, COSV100967053; called by muse, mutect2, varscan2
- C2CD2 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as COSV100298145; called by muse, mutect2, varscan2
- C2orf16 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV68646966; called by muse, mutect2, varscan2
- CA9 | c.1320-1G>A p.X440_splice | Splice Site (SNP) | VAF 18/177 reads (10%) | catalogued as COSV100253223; called by muse, mutect2, varscan2
- CACNA1D | c.788C>T p.S263F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99858043; called by muse, mutect2, varscan2
- CACNA1S | c.4963C>T p.P1655S | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100754976; called by muse, mutect2, varscan2
- CACNA2D1 | c.898G>A p.D300N | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100666598, COSV62392991; called by muse, mutect2, varscan2
- CADM2 | c.148G>A p.D50N (on ENST00000407528 / NM_001167674.2; = p.D52N on NM_153184.4) | Missense Mutation (SNP) | VAF 37/68 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101055263; called by muse, mutect2, varscan2
- CAPN5 | c.796G>A p.G266S (on ENST00000456580; = p.G226S on NM_004055.5) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.091); catalogued as rs782553249, COSV53692592; called by muse, mutect2, varscan2
- CARD10 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52660151; called by muse, mutect2, varscan2
- CARD11 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 34/63 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as rs1208108119, COSV62720578; called by muse, mutect2, varscan2
- CATSPERB | c.2773G>A p.D925N | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV56425368, COSV99831242; called by muse, varscan2
- CBFA2T3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV51934800; called by muse, mutect2, varscan2
- CBLN4 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.05); catalogued as COSV50352059; called by muse, mutect2, varscan2
- CCDC15 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.783); catalogued as COSV100776969; called by muse, mutect2, varscan2
- CCDC163 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.748); catalogued as COSV59151305; called by muse, mutect2, varscan2
- CCDC27 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as COSV99622440; called by muse, mutect2, varscan2
- CCDC33 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58357286; called by muse, mutect2, varscan2
- CCDC34 | c.907+1G>A p.X303_splice | Splice Site (SNP) | VAF 42/87 reads (48%) | catalogued as COSV100156564; called by muse, mutect2, varscan2
- CCDC60 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs764208425, COSV59540294; called by muse, mutect2, varscan2
- CCDC60 | c.1237G>A p.E413K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV100555050; called by muse, mutect2, varscan2
- CCDC68 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV100491572; called by muse, mutect2, varscan2
- CCDC93 | c.962C>T p.S321F | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1355392634, COSV60119489; called by muse, mutect2, varscan2
- CCR4 | c.922G>A p.G308R | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100447392; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, mutect2, varscan2
- CD163L1 | c.2396G>A p.G799E | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100550051; called by muse, mutect2, varscan2
- CDH8 | c.2002G>A p.D668N | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.148); catalogued as rs1567404075, COSV100180310; called by muse, mutect2, varscan2
- CDH8 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 24/59 reads (41%) | catalogued as rs267604590, COSV100182320, COSV54846997; called by muse, mutect2, varscan2
- CECR2 | c.3992C>T p.S1331L (on ENST00000342247 / NM_001290047.2; = p.S1147L on NM_001290046.1) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.17); catalogued as COSV99377856; called by muse, mutect2, varscan2
- CELA2A | c.130-1G>A p.X44_splice | Splice Site (SNP) | VAF 13/80 reads (16%) | catalogued as COSV100657558; called by muse, mutect2, varscan2
- CELA2A | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.99); PolyPhen benign (0.07); catalogued as COSV100657559; called by muse, mutect2, varscan2
- CELSR2 | c.3802C>T p.P1268S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV99603759; called by muse, mutect2, varscan2
- CFAP57 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV100993933; called by muse, mutect2, varscan2
- CHD6 | c.7703C>T p.T2568I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100950966; called by muse, mutect2, varscan2
- CHD6 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV58555044; called by muse, mutect2, varscan2
- CKAP4 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100952449; called by muse, mutect2
- CLDN4 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV52894859; called by muse, mutect2, varscan2
- CLEC4D | c.508C>A p.H170N | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV100222995; called by muse, mutect2, varscan2
- CLSTN2 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs900952461, COSV71724080; called by muse, mutect2, varscan2
- CMYA5 | c.6493G>A p.D2165N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs768992517, COSV71405664, COSV71410416; called by muse, mutect2, varscan2
- CNGA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55624555; called by muse, mutect2, varscan2
- CNKSR2 | c.2672G>A p.G891E | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99668427; called by muse, varscan2
- CNNM4 | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs762759439, COSV100998656; called by muse, mutect2, varscan2
- COL4A4 | c.2038G>A p.G680S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868455763, COSV100306800; called by muse, mutect2, varscan2
- COL5A3 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV99318843; called by muse, mutect2, varscan2
- COL8A1 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.481); catalogued as COSV99657050, COSV99657689; called by muse, mutect2, varscan2
- COPE | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV99447438; called by muse, mutect2, varscan2
- CPN2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV100103081; called by muse, mutect2, varscan2
- CPSF6 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.981); catalogued as COSV57017291; called by muse, mutect2, varscan2
- CR1 | c.5308G>A p.E1770K | Missense Mutation (SNP) | VAF 49/229 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65455974; called by muse, mutect2, varscan2
- CSMD1 | c.4180G>A p.D1394N (on ENST00000520002; = p.D1393N on NM_033225.6) | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779702652, COSV59321276, COSV99045826; called by muse, mutect2, varscan2
- CSMD2 | c.4678G>A p.D1560N | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99589625; called by muse, mutect2, varscan2
- CSMD3 | c.1789G>A p.E597K (on ENST00000297405 / NM_001363185.1; = p.E493K on NM_052900.3) | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99833552; called by muse, mutect2, varscan2
- CSMD3 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs866443539, COSV52121298; called by muse, mutect2, varscan2
- CTLA4 | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.127); catalogued as COSV55592255; called by muse, mutect2, varscan2
- CTNNA2 | c.2410G>A p.G804R | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100560554; called by muse, mutect2, varscan2
- CXorf66 | c.560G>A p.S187N | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV100983876; called by muse, mutect2, varscan2
- CYLC2 | c.653A>G p.K218R | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV66336764; called by muse, mutect2, varscan2
- CYP2S1 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV100027455; called by muse, varscan2
- DAGLA | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV99944143; called by muse, mutect2, varscan2
- DAW1 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.17); catalogued as COSV100006163; called by muse, mutect2, varscan2
- DCDC1 | c.2650G>A p.E884K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV100338207; called by muse, mutect2, varscan2
- DCTN1 | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62620969; called by muse, mutect2, varscan2
- DCUN1D4 | c.311A>T p.K104I | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100584492; called by muse, mutect2, varscan2
- DDX11 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV99299575; called by muse, mutect2, varscan2
- DDX18 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV99604530; called by muse, mutect2, varscan2
- DDX3X | c.1663T>A p.L555M (on ENST00000399959; = p.L556M on NM_001356.5) | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101302431; called by muse, mutect2, varscan2
- DDX3X | c.1664T>A p.L555* (on ENST00000399959; = p.L556* on NM_001356.5) | Nonsense Mutation (SNP) | VAF 38/57 reads (67%) | catalogued as COSV101302432; called by muse, mutect2, varscan2
- DDX4 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.999); catalogued as COSV100737505; called by muse, mutect2, varscan2
- DEFB113 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as rs1291998038, COSV100435392; called by muse, mutect2, varscan2
- DHRSX | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58140375; called by muse, mutect2, varscan2
- DHX29 | c.295A>T p.I99F | Missense Mutation (SNP) | VAF 32/57 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99287257; called by muse, mutect2, varscan2
- DKKL1 | c.548C>T p.A183V | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99678673; called by muse, mutect2, varscan2
- DMBT1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 66/100 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780912281, COSV57532698; called by muse, mutect2, varscan2
- DMXL2 | c.6229C>T p.L2077F | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99196339; called by muse, mutect2, varscan2
- DNAH10 | c.8237G>A p.R2746K (on ENST00000409039; = p.R2685K on NM_207437.3) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101292232; called by muse, mutect2
- DNAH7 | c.6220G>A p.D2074N | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs868305494, COSV100415103; called by muse, mutect2, varscan2
- DNAH7 | c.5870G>A p.R1957Q | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.458); catalogued as rs200790432, COSV56760571; called by muse, mutect2, varscan2
- DNAH7 | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs192646926; called by muse, mutect2, varscan2
- DNAJB13 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1438382403, COSV100334496; called by muse, mutect2, varscan2
- DNAJC13 | c.2812A>G p.I938V | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99607209; called by muse, mutect2, varscan2
- DNTTIP1 | c.979C>T p.P327S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV54754500; called by muse, mutect2, varscan2
- DOCK1 | c.1741G>A p.G581S | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV99729411; called by muse, mutect2, varscan2
- DOCK3 | c.1987G>A p.V663I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99811713, COSV99814675; called by muse, mutect2, varscan2
- DOK6 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.023); catalogued as COSV66926338; called by muse, mutect2, varscan2
- DOP1B | c.2366G>T p.S789I | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); catalogued as COSV101215334; called by muse, mutect2
- DPP10 | c.469T>A p.Y157N | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100064592; called by muse, mutect2, varscan2
- DPPA4 | c.712C>T p.L238F | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.906); catalogued as rs1219980797, COSV100169416; called by muse, mutect2, varscan2
- DRP2 | c.1912T>C p.F638L | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100871901; called by muse, mutect2, varscan2
- DSCAM | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs772072144, COSV101260041; called by muse, mutect2, varscan2
- DSCAML1 | c.3445+1G>A p.X1149_splice (on ENST00000321322; = p.X1089_splice on NM_020693.4) | Splice Site (SNP) | VAF 22/36 reads (61%) | catalogued as COSV100355881; called by muse, mutect2, varscan2
- DSEL | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100025622; called by muse, mutect2, varscan2
- DSG3 | c.2681G>A p.G894E | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV57128265; called by muse, mutect2, varscan2
- DSG4 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.585); catalogued as COSV100355872; called by muse, mutect2
- DSG4 | c.1277+1G>A p.X426_splice | Splice Site (SNP) | VAF 9/12 reads (75%) | catalogued as COSV100355874; called by muse, mutect2
- DYNC2H1 | c.12268G>T p.V4090F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100518495; called by muse, mutect2, varscan2
- DZIP3 | c.3173G>A p.R1058Q | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs138409858; called by muse, mutect2, varscan2
- EBF2 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs780765365, COSV68781371; called by muse, mutect2, varscan2
- ECPAS | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs866956418, COSV99398212; called by muse, mutect2, varscan2
- EDF1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV99808020; called by muse, mutect2, varscan2
- EEPD1 | c.1043G>T p.G348V | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99632214; called by muse, mutect2, varscan2
- EFCAB11 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as rs751376335, COSV57445355; called by muse, mutect2, varscan2
- EGFL6 | c.565C>T p.R189* | Nonsense Mutation (SNP) | VAF 27/39 reads (69%) | catalogued as rs199619027, COSV100789878; called by muse, mutect2, varscan2
- ELOA3C | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as COSV55304720; called by muse, mutect2
- ENAH | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.986); catalogued as COSV99490600; called by muse, mutect2, varscan2
- ENPP2 | c.1265del p.K422Sfs*4 (on ENST00000075322 / NM_001040092.3; = p.K474Sfs*4 on NM_006209.5) | Frame Shift Del (DEL) | VAF 39/169 reads (23%) | catalogued as COSV99308227; called by mutect2, pindel, varscan2
- ENPP2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754090722, COSV99308238; called by muse, mutect2, varscan2
- ENPP5 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100040451; called by muse, mutect2, varscan2
- ENTHD1 | c.1541G>A p.G514E | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100288713; called by muse, mutect2, varscan2
- EP400 | c.8581G>A p.A2861T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.991); catalogued as COSV57782364; called by muse, mutect2, varscan2
- EPN3 | c.1150C>T p.P384S | Missense Mutation (SNP) | VAF 44/61 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV99276941; called by muse, mutect2, varscan2
- ERICH5 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100582770; called by muse, mutect2, varscan2
- ERN2 | c.299G>A p.G100E | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1039118755, COSV56836130; called by muse, mutect2, varscan2
- ESRRA | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.908); catalogued as rs527493990, COSV50007327, COSV99134597; called by muse, mutect2, varscan2
- ESYT3 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679808; called by muse, mutect2, varscan2
- EXPH5 | c.1514G>A p.R505K | Missense Mutation (SNP) | VAF 39/64 reads (61%) | SIFT tolerated (0.19); PolyPhen benign (0.331); catalogued as COSV56205838; called by muse, mutect2, varscan2
- EYS | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs577044383, COSV60977174, COSV60983569; called by muse, mutect2, varscan2
- F11R | c.242-2A>T p.X81_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99231028; called by muse, mutect2, varscan2
- F5 | c.5843G>A p.W1948* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100889091; called by muse, mutect2, varscan2
- FAF1 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100875539; called by muse, mutect2, varscan2
- FAM184A | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV100137761; called by muse, mutect2, varscan2
- FAM47C | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.999); catalogued as COSV63723515; called by muse, mutect2, varscan2
- FAM83B | c.2659C>T p.P887S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100174441; called by muse, mutect2, varscan2
- FAM83B | c.2993G>A p.G998E | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs267601082, COSV60919114; called by muse, mutect2, varscan2
- FAR2 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1565498021, COSV99479060; called by muse, mutect2, varscan2
- FAT3 | c.5984A>G p.N1995S | Missense Mutation (SNP) | VAF 45/73 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99965803; called by muse, mutect2, varscan2
- FBLL1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.74); catalogued as COSV100606160; called by muse, mutect2, varscan2
- FCGR3A | c.99A>C p.Q33H | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100914648; called by muse, mutect2, varscan2
- FCN2 | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52477935; called by muse, mutect2, varscan2
- FCRL3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as rs760856382, COSV100943184; called by mutect2, varscan2
- FER1L6 | c.5551C>G p.R1851G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs201702749, COSV101205824; called by mutect2, varscan2
- FFAR3 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760651767, COSV100588192, COSV59908950; called by muse, mutect2, varscan2
- FGD5 | c.3884G>A p.G1295D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV99547976; called by muse, mutect2, varscan2
- FIBCD1 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 39/55 reads (71%) | catalogued as rs1353614365, COSV99447039; called by muse, mutect2, varscan2
- FLG2 | c.5326G>A p.D1776N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs555660257, COSV66168591; called by muse, mutect2, varscan2
- FLVCR2 | c.1306G>T p.G436C | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99471283; called by muse, mutect2, varscan2
- FMN2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs370099468; called by muse, mutect2, varscan2
- FMN2 | c.3559C>A p.P1187T | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV100144907, COSV60438603; called by muse, mutect2, varscan2
- FMN2 | c.3560C>T p.P1187L | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs372947608; called by muse, mutect2, varscan2
- FOXA1 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV51650701; called by muse, mutect2
- FRG2B | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.998); catalogued as rs1175817076, COSV71042772, COSV71044237; called by muse, mutect2
- FRMPD2 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100563811, COSV59714622; called by muse, varscan2
- FRMPD2 | c.1354C>T p.R452W | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141989722; called by muse, varscan2
- FRY | c.629A>G p.K210R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.345); catalogued as COSV100969224; called by muse, mutect2, varscan2
- FRY | c.4904G>A p.G1635E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.456); catalogued as COSV100969225, COSV66571562; called by muse, mutect2, varscan2
- FSIP2 | c.19925G>A p.R6642Q | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs773551789, COSV58099435; called by muse, mutect2, varscan2
- FZD10 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472348; called by muse, mutect2, varscan2
- GABRG1 | c.964A>T p.K322* | Nonsense Mutation (SNP) | VAF 5/66 reads (8%) | catalogued as COSV99777962; called by muse, mutect2
- GABRR1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV101033901; called by muse, mutect2, varscan2
- GALNT17 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV100353875; called by muse, mutect2, varscan2
- GALNT8 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.382); catalogued as COSV52901981, COSV52902674; called by muse, mutect2, varscan2
- GBE1 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV101450149; called by muse, mutect2, varscan2
- GIMAP6 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV61032855; called by muse, mutect2, varscan2
- GLRA3 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99927516; called by muse, mutect2, varscan2
- GOLGB1 | c.4472C>T p.S1491F | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61471261; called by muse, mutect2, varscan2
- GOLGB1 | c.4177A>T p.K1393* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as COSV100510814; called by muse, mutect2, varscan2
- GPATCH2L | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 17/34 reads (50%) | catalogued as COSV99833595; called by muse, mutect2, varscan2
- GPBP1L1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV99322277; called by muse, mutect2, varscan2
- GPC5 | c.1498G>A p.D500N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65589742; called by muse, mutect2, varscan2
- GPLD1 | c.944G>A p.S315N | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100015306; called by muse, mutect2, varscan2
- GPR158 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.071); catalogued as COSV66265839; called by muse, mutect2, varscan2
- GRID2 | c.1588C>T p.R530C | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749223378, COSV56185857, COSV99944022; called by muse, mutect2, varscan2
- GRIK1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs780797570, COSV58712360, COSV58716986; called by muse, mutect2, varscan2
- GRIK4 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV101483580; called by muse, mutect2, varscan2
- GRIK4 | c.1379G>T p.R460L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as COSV101483402, COSV101483610; called by muse, mutect2, varscan2
- GRIN2A | c.2011C>A p.Q671K | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100409689, COSV58052583; called by muse, mutect2, varscan2
- GRM3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.177); catalogued as rs267601603, COSV64469163; called by muse, mutect2, varscan2
- GRM3 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs371949904; called by muse, mutect2, varscan2
- GRM8 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.781); catalogued as COSV100282798; called by muse, mutect2, varscan2
- H3C2 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV52517730, COSV52518686, COSV99451691; called by muse, mutect2, varscan2
- HAS2 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.122); catalogued as COSV100391776; called by muse, mutect2, varscan2
- HECTD1 | c.5326C>T p.P1776S | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67949701; called by muse, mutect2, varscan2
- HNRNPM | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 72/103 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV100335151; called by muse, mutect2, varscan2
- HOXA5 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56072711, COSV99762291; called by muse, mutect2, varscan2
- HSPA2 | c.1426C>T p.Q476* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV99904929; called by muse, mutect2, varscan2
- HSPB7 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.248); catalogued as COSV100317911, COSV58893148; called by muse, mutect2, varscan2
- HTR4 | c.1058G>A p.G353E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as COSV58794948; called by muse, mutect2, varscan2
- HYOU1 | c.2827C>T p.P943S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.388); catalogued as rs201317769, COSV101345593; called by muse, mutect2, varscan2
- IDO2 | c.1186G>A p.D396N (on ENST00000389060; = p.D409N on NM_194294.2) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as rs756438349, COSV100584733; called by muse, mutect2, varscan2
- IDUA | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.66); PolyPhen benign (0.05); catalogued as COSV99925926; called by muse, mutect2, varscan2
- IGF2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 119/226 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV100324046; called by muse, mutect2, varscan2
- IGHV3-53 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as rs534698697; called by muse, mutect2, varscan2
- IGHV4-34 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs3814933; called by muse, mutect2, varscan2
- IGSF10 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99179840; called by muse, mutect2, varscan2
- IKBIP | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100689780, COSV61082574; called by muse, mutect2, varscan2
- IL1RL2 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV51820022; called by muse, mutect2, varscan2
- IL22RA1 | c.1481G>A p.G494D | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs137928018, COSV99582974; called by muse, mutect2, varscan2
- IL22RA1 | c.1480G>A p.G494S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV54628681; called by muse, mutect2, varscan2
- IL5RA | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV99842976; called by muse, mutect2, varscan2
- IMPG1 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as COSV64058371; called by muse, mutect2, varscan2
- IMPG1 | c.563-1G>A p.X188_splice | Splice Site (SNP) | VAF 14/52 reads (27%) | catalogued as rs1446011966, COSV100886349; called by muse, mutect2, varscan2
- INMT | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs757385464, COSV50001725; called by muse, mutect2, varscan2
- INO80D | c.2054T>A p.L685* | Nonsense Mutation (SNP) | VAF 20/54 reads (37%) | catalogued as COSV101305827; called by muse, mutect2, varscan2
- INTS1 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 61/105 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs867164699, COSV101247878, COSV101247960; called by muse, mutect2, varscan2
- INTS8 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.121); catalogued as COSV100569257; called by muse, mutect2, varscan2
- ISM1 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99339845, COSV99339992; called by muse, mutect2, varscan2
- ITGA2 | c.347G>A p.G116D | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99670755; called by muse, mutect2, varscan2
- ITGAD | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.085); catalogued as COSV54932929; called by muse, mutect2, varscan2
- ITGAV | c.1774C>T p.R592W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs200949549, COSV53709675; called by muse, mutect2, varscan2
- ITIH2 | c.495C>A p.F165L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100623282; called by muse, mutect2, varscan2
- ITPR1 | c.2275C>T p.Q759* (on ENST00000354582; = p.Q744* on NM_002222.7) | Nonsense Mutation (SNP) | VAF 25/52 reads (48%) | catalogued as COSV100231006; called by muse, mutect2, varscan2
- JAKMIP2 | c.2428G>A p.G810R | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1169223817, COSV99508263; called by muse, mutect2, varscan2
- JPH1 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60615115; called by muse, mutect2, varscan2
- KANSL3 | c.2456C>T p.P819L (on ENST00000666923 / NM_001349262.2; = p.P793L on NM_001115016.3) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV100831097; called by muse, mutect2
- KBTBD12 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100675420, COSV59682606; called by muse, mutect2, varscan2
- KCNB2 | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101578615, COSV101578778; called by muse, mutect2, varscan2
- KCNJ5 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.69); PolyPhen probably damaging (1); catalogued as rs761349623, COSV100610658; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNK10 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs867773131, COSV56649573; called by muse, mutect2, varscan2
- KCNMB1 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV99210975; called by muse, mutect2, varscan2
- KCNT2 | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs267598261, COSV54073484; called by muse, mutect2, varscan2
- KCNT2 | c.2035G>A p.G679R | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99653511; called by muse, mutect2, varscan2
- KDM5C | c.4615C>T p.P1539S | Missense Mutation (SNP) | VAF 29/34 reads (85%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100949140; called by muse, mutect2, varscan2
- KIAA1109 | c.13984C>T p.H4662Y | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1313755115, COSV99163108; called by muse, mutect2, varscan2
- KIF1A | c.108C>A p.T36= | Splice Region (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100240857; called by muse, varscan2
- KIR3DL3 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52551039; called by muse, mutect2, varscan2
- KLHL13 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1056231947, COSV99451616; called by muse, mutect2, varscan2
- KLK8 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99143962; called by muse, mutect2
- KLKB1 | c.752C>T p.S251L | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV99249931; called by muse, mutect2, varscan2
- KMT2B | c.2306T>C p.M769T | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99386039; called by muse, mutect2, varscan2
- KMT2B | c.4612C>T p.H1538Y | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99719555; called by muse, mutect2, varscan2
- KRT4 | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV53407733, COSV99542905; called by muse, mutect2, varscan2
- KRTAP10-3 | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV100553348; called by muse, mutect2, varscan2
- KTN1 | c.3340G>A p.E1114K (on ENST00000395314 / NM_001271014.2; = p.E1085K on NM_004986.4) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.221); catalogued as COSV100618324; called by muse, mutect2, varscan2
- L3MBTL3 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as rs901170995, COSV100696122; called by muse, mutect2, varscan2
- LAMA1 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.993); catalogued as rs1169588808, COSV101056295; called by muse, mutect2, varscan2
- LGALS12 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.763); catalogued as COSV55372206; called by muse, mutect2, varscan2
- LHCGR | c.496G>T p.G166* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV54303900, COSV99683666; called by muse, mutect2, varscan2
- LIG4 | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV100799897, COSV100800002; called by muse, mutect2, varscan2
- LILRA2 | c.214C>T p.R72W | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764683666, COSV99253321; called by muse, mutect2, varscan2
- LILRA2 | c.1324C>T p.P442S (on ENST00000391738 / NM_001130917.3; = p.P425S on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.107); catalogued as COSV99253327; called by muse, mutect2, varscan2
- LIMCH1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100573798; called by muse, mutect2, varscan2
- LIN7A | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as COSV99692093; called by muse, mutect2, varscan2
- LINGO2 | c.1490C>T p.S497F | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.739); catalogued as COSV58059883; called by muse, mutect2, varscan2
- LMOD3 | c.652C>A p.P218T | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs1206949403, COSV101341996; called by muse, mutect2, varscan2
- LMTK2 | c.4483G>A p.G1495R | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312632974, COSV99806794; called by mutect2, varscan2
- LRBA | c.7003C>T p.H2335Y | Missense Mutation (SNP) | VAF 98/174 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.106); catalogued as COSV100841498; called by muse, mutect2, varscan2
- LRP1B | c.13580G>A p.G4527E | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.617); catalogued as COSV101256462; called by muse, mutect2, varscan2
- LRP1B | c.9556C>T p.R3186C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as rs567834250, COSV67185177; called by muse, mutect2, varscan2
- LRP1B | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs776305678, COSV67188037; called by muse, mutect2, varscan2
- LRP1B | c.695G>A p.G232E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV67204342; called by muse, mutect2, varscan2
- LRP2 | c.6284G>A p.R2095Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs769929318, COSV55542779; called by muse, mutect2, varscan2
- LRP2 | c.4670T>C p.L1557P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99788317; called by muse, mutect2, varscan2
- LRRC28 | c.649A>C p.K217Q | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as COSV100113565; called by muse, mutect2, varscan2
- LRRC7 | c.1546G>A p.D516N (on ENST00000651989 / NM_001370785.2; = p.D483N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.437); catalogued as COSV50442528, COSV50591868; called by muse, mutect2, varscan2
- LRRIQ3 | c.1392A>T p.K464N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV100598795; called by muse, mutect2, varscan2
- LRRK1 | c.5206G>A p.V1736I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99439737; called by muse, mutect2, varscan2
- LTBP2 | c.4333G>A p.G1445R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56215685; called by muse, mutect2, varscan2
- LTBP4 | c.3502C>A p.P1168T (on ENST00000308370 / NM_001042544.1; = p.P1131T on NM_003573.2) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.628); catalogued as COSV99191919; called by muse, mutect2, varscan2
- LTN1 | c.5171G>A p.G1724D | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100797983; called by muse, mutect2, varscan2
- LTN1 | c.304G>T p.V102F | Missense Mutation (SNP) | VAF 66/171 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100797984; called by muse, mutect2, varscan2
- LYRM1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99533925; called by muse, mutect2, varscan2
- MAB21L4 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs202161469, COSV100278492; called by muse, mutect2, varscan2
- MADD | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 37/63 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV60631555; called by muse, mutect2, varscan2
- MAGEC1 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 22/27 reads (81%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as rs1388963604, COSV53581563; called by muse, mutect2, varscan2
- MAGEC1 | c.1124T>C p.I375T | Missense Mutation (SNP) | VAF 81/119 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.307); catalogued as COSV53571047; called by muse, mutect2, varscan2
- MAGEC3 | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 31/43 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as rs1033417832, COSV71610262; called by muse, mutect2, varscan2
- MAGEL2 | c.1990C>T p.P664S | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); catalogued as COSV100045917, COSV58565796; called by muse, mutect2, varscan2
- MAJIN | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.439); catalogued as COSV100104366; called by muse, mutect2, varscan2
- MAMDC2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1434837171, COSV101015468; called by muse, mutect2, varscan2
- MAP2K7 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 40/46 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101209036; called by muse, mutect2, varscan2
- MAP2K7 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 41/46 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101209037; called by muse, mutect2, varscan2
- MAP3K5 | c.2114G>A p.R705K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as COSV100752788; called by muse, mutect2, varscan2
- MAP7 | c.2051G>A p.G684D | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1366073225, COSV100643864; called by muse, mutect2, varscan2
- MARCO | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.299); catalogued as COSV100503438; called by muse, mutect2, varscan2
- MBTPS1 | c.2719C>T p.R907W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs147197996, COSV100597595; called by muse, mutect2, varscan2
- MCM10 | c.1319C>T p.P440L (on ENST00000484800 / NM_182751.3; = p.P439L on NM_018518.5) | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1458119522, COSV101098103; called by muse, mutect2, varscan2
- MCTP1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV100387106; called by muse, mutect2, varscan2
- MDGA1 | c.2237C>T p.P746L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs774672732, COSV51800521; called by muse, mutect2, varscan2
- MDN1 | c.16340G>A p.G5447E | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101021286; called by muse, mutect2, varscan2
- MECOM | c.2845G>A p.E949K (on ENST00000468789 / NM_001105078.4; = p.E1137K on NM_004991.4) | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.628); catalogued as COSV99244666; called by muse, mutect2, varscan2
- MECOM | c.424G>A p.D142N (on ENST00000468789 / NM_001105078.4; = p.D330N on NM_004991.4) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244667; called by muse, mutect2, varscan2
- MINDY4 | c.1786G>A p.G596R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518605; called by muse, mutect2, varscan2
- MMD2 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.475); catalogued as rs780400553, COSV101287007, COSV99065601; called by muse, mutect2, varscan2
- MMP1 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs973172732, COSV100187944; called by muse, varscan2
- MMP20 | c.742T>C p.Y248H | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99497702; called by muse, mutect2, varscan2
- MMP20 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV52777635; called by muse, mutect2, varscan2
- MMUT | c.1382A>G p.E461G | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99222324; called by muse, mutect2, varscan2
- MORC1 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.036); catalogued as COSV51717090; called by muse, mutect2, varscan2
- MORN1 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV101047968; called by muse, mutect2, varscan2
- MOV10 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.363); catalogued as rs372683047; called by muse, mutect2, varscan2
- MROH2B | c.3874G>A p.E1292K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV68183148; called by muse, mutect2, varscan2
- MSI2 | c.653-1G>A p.X218_splice | Splice Site (SNP) | VAF 28/37 reads (76%) | catalogued as COSV99402494; called by muse, mutect2, varscan2
- MSI2 | c.653G>A p.G218E | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV99402496; called by muse, mutect2, varscan2
- MSTN | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99640680; called by muse, mutect2, varscan2
- MTPAP | c.1705T>C p.F569L | Missense Mutation (SNP) | VAF 59/149 reads (40%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV99554063; called by muse, mutect2, varscan2
- MUC16 | c.16641G>A p.M5547I | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV67506814; called by muse, mutect2, varscan2
- MUC5AC | c.14569C>T p.P4857S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100611432; called by muse, mutect2, varscan2
- MUC5B | c.4898C>T p.P1633L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101500298; called by muse, mutect2, varscan2
- MUC5B | c.9388G>A p.G3130R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV101500299; called by muse, mutect2, varscan2
- MUC6 | c.1449G>C p.K483N | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); catalogued as COSV101424576; called by muse, mutect2, varscan2
- MYH15 | c.2138G>A p.G713E | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99843189; called by muse, mutect2, varscan2
- MYH7B | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV99482755; called by muse, mutect2, varscan2
- MYLK2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 66/154 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.259); catalogued as COSV101044579, COSV101044658; called by muse, mutect2, varscan2
- MYLK3 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs1369361207, COSV101189117; called by muse, mutect2, varscan2
- MYO18B | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV100123574; called by muse, mutect2, varscan2
- MYO1B | c.3110T>C p.V1037A (on ENST00000304164; = p.V979A on NM_012223.5) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV100269132; called by muse, mutect2, varscan2
- MYO3B | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs369752113; called by muse, mutect2, varscan2
- MYOM3 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100292932; called by muse, mutect2
- NACA | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100771308; called by muse, mutect2, varscan2
- NAV3 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs772277113, COSV57066953, COSV99890864; called by muse, mutect2, varscan2
- NAV3 | c.3710G>A p.G1237E | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57071576; called by muse, mutect2
- NECTIN2 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.513); catalogued as COSV99374986; called by muse, mutect2, varscan2
- NEDD9 | c.2453C>T p.S818F | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101060834; called by muse, mutect2, varscan2
- NEUROD4 | c.63G>A p.M21I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs552404160, COSV54472554; called by muse, mutect2, varscan2
- NIN | c.5488C>T p.H1830Y (on ENST00000382041 / NM_182946.1; = p.H1117Y on NM_016350.4) | Missense Mutation (SNP) | VAF 58/97 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV99813439; called by muse, mutect2, varscan2
- NLGN4X | c.2362G>A p.G788R | Missense Mutation (SNP) | VAF 47/62 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV52039786, COSV99323267; called by muse, mutect2, varscan2
- NLRP4 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.606); catalogued as COSV100016259; called by muse, mutect2, varscan2
- NME7 | c.438C>T p.F146= | Splice Region (SNP) | VAF 38/202 reads (19%) | catalogued as rs752492264, COSV100891026; called by muse, mutect2, varscan2
- NOL4 | c.1279G>A p.V427I | Missense Mutation (SNP) | VAF 24/39 reads (62%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV52356313; called by muse, mutect2, varscan2
- NOVA1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1200412725, COSV57472189; called by muse, mutect2, varscan2
- NPHP1 | c.2131C>T p.H711Y (on ENST00000393272 / NM_207181.4; = p.H712Y on NM_000272.5) | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100338039; called by muse, mutect2, varscan2
- NPR3 | c.833G>A p.G278D | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs1286504322, COSV99422915; called by muse, mutect2, varscan2
- NRAP | c.4083G>A p.M1361I (on ENST00000359988 / NM_001322945.2; = p.M1326I on NM_006175.4) | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as COSV100748423; called by muse, mutect2, varscan2
- NTRK1 | c.1747C>T p.R583C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs371344688, COSV62324100; called by muse, mutect2, varscan2
- NUP58 | c.1587T>A p.F529L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.979); catalogued as COSV101098732; called by muse, mutect2, varscan2
- OBSCN | c.15983C>T p.S5328F | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.273); catalogued as rs553002345, COSV99477370; called by muse, mutect2, varscan2
- OCM2 | c.148T>C p.F50L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99990804; called by muse, mutect2, varscan2
- OR10A3 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs751844601, COSV62459225, COSV62459990; called by muse, mutect2, varscan2
- OR10G9 | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100901601; called by muse, mutect2, varscan2
- OR14K1 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV51721143, COSV99315167; called by muse, mutect2, varscan2
- OR2L2 | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1266416562, COSV63550563, COSV63562056; called by muse, mutect2, varscan2
- OR2T1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs769406328, COSV63541354; called by muse, mutect2, varscan2
- OR2T2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.783); catalogued as COSV100737660; called by muse, mutect2, varscan2
- OR2T8 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV100178248; called by muse, mutect2, varscan2
- OR4A15 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.901); catalogued as rs370541816, COSV59036470; called by muse, mutect2, varscan2
- OR4C46 | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60218398; called by muse, mutect2, varscan2
- OR51G2 | c.780G>A p.M260I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as COSV100432130; called by muse, mutect2, varscan2
- OR52E2 | c.260T>C p.F87S | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58612612; called by muse, mutect2, varscan2
- OR52E6 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100259315; called by muse, mutect2, varscan2
- OR56B4 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as COSV57204248; called by muse, mutect2
- OR6C6 | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV64455747; called by muse, mutect2, varscan2
- OR6C6 | c.307C>T p.L103F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as rs956997118, COSV64456259; called by muse, mutect2, varscan2
- OR6C65 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV65568097; called by muse, mutect2, varscan2
- OR8D1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.185); catalogued as COSV63441945; called by muse, mutect2, varscan2
- OR9K2 | c.683C>T p.S228L (on ENST00000305377; = p.S206L on NM_001005243.1) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as rs368474784; called by muse, mutect2, varscan2
- OTOL1 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100019960; called by muse, mutect2, varscan2
- P2RY10 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99409116; called by muse, mutect2, varscan2
- PABPC1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100589535; called by mutect2, varscan2
- PACRG | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1319040438, COSV61295273; called by muse, mutect2, varscan2
- PAK5 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV100781316; called by muse, mutect2, varscan2
- PALB2 | c.1777C>T p.H593Y | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV55162332; called by muse, mutect2, varscan2
- PAPLN | c.2210C>T p.P737L (on ENST00000554301; = p.P710L on NM_173462.4) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53713323, COSV99389054; called by muse, mutect2, varscan2
- PAPPA | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs868292130, COSV60292745; called by muse, mutect2, varscan2
- PAPPA2 | c.2890G>A p.D964N | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.709); catalogued as rs201513629, COSV62798363; called by muse, mutect2, varscan2
- PAXIP1 | c.2450C>T p.P817L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV101249651; called by muse, mutect2, varscan2
- PAXIP1 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.845); catalogued as rs763531386, COSV101249654; called by muse, mutect2, varscan2
- PCDH15 | c.4990T>A p.F1664I | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.084); catalogued as COSV100220428, COSV57272431; called by muse, mutect2, varscan2
- PCDHB11 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100696901; called by muse, mutect2, varscan2
- PCLO | c.5810G>A p.R1937Q | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs750274296, COSV61629961; called by muse, mutect2, varscan2
- PCLO | c.4689G>A p.M1563I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV61662383, COSV61666729; called by muse, mutect2, varscan2
- PCNT | c.6697G>A p.D2233N | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100855459; called by muse, mutect2, varscan2
- PCNX1 | c.4508C>T p.P1503L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99455519; called by muse, mutect2, varscan2
- PCNX2 | c.5698C>T p.P1900S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs758882392, COSV99267416; called by muse, mutect2, varscan2
- PCNX2 | c.2891C>T p.S964F | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV50825215; called by muse, mutect2, varscan2
- PCSK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs770310795, COSV60734749, COSV60737225; called by muse, mutect2, varscan2
- PDE10A | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100605048; called by muse, mutect2, varscan2
- PDE1A | c.1608A>C p.*536Yext*15 | Nonstop Mutation (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100114202; called by muse, mutect2, varscan2
- PDE1B | c.1541C>T p.S514F | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs749477163, COSV99226270; called by muse, mutect2, varscan2
- PDE6B | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV99727471; called by muse, mutect2, varscan2
- PDPR | c.2566T>C p.Y856H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV99848277; called by muse, mutect2, varscan2
- PHLDB2 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV101208512; called by muse, mutect2, varscan2
- PIGT | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV99648938, COSV99649101; called by muse, mutect2, varscan2
- PITRM1 | c.3094C>T p.P1032S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99828759; called by muse, mutect2, varscan2
- PKD1L1 | c.7496G>A p.G2499E | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99219614; called by muse, mutect2
- PKHD1L1 | c.3305T>C p.V1102A | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV101006071; called by muse, mutect2, varscan2
- PKP4 | c.958G>A p.D320N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as COSV101080881; called by muse, mutect2, varscan2
- PLCB1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100570877; called by muse, mutect2, varscan2
- PLCB1 | c.1235A>C p.E412A | Missense Mutation (SNP) | VAF 44/113 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100570878; called by muse, mutect2, varscan2
- PLCB3 | c.2312C>T p.S771L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749213059, COSV54191185; called by mutect2, varscan2
- PLCB4 | c.2632G>A p.A878T | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1312728965, COSV99595366; called by muse, mutect2, varscan2
- PLCE1 | c.5129C>T p.P1710L | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as COSV99594836; called by muse, mutect2, varscan2
- PLEKHG6 | c.1798G>A p.G600R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.169); catalogued as COSV50600093; called by muse, mutect2, varscan2
- PLXDC2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.641); catalogued as rs777126319, COSV65919121; called by muse, mutect2, varscan2
- PLXNA2 | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as rs1553272777, COSV100885436; called by muse, mutect2, varscan2
- PNPLA1 | c.937G>A p.E313K (on ENST00000394571 / NM_001374623.1; = p.E218K on NM_173676.2) | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as COSV100463063; called by muse, mutect2, varscan2
- POLG | c.1708C>A p.P570T | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV99174749; called by muse, mutect2, varscan2
- POTEE | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100387857, COSV100388399; called by muse, mutect2, varscan2
- PPP1R12B | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs918521930, COSV99294833; called by muse, mutect2, varscan2
- PRDM15 | c.3338C>T p.T1113I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV99520039; called by muse, mutect2, varscan2
- PRG4 | c.3617G>A p.G1206E | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63355048; called by muse, mutect2, varscan2
- PRKAA2 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.017); catalogued as rs1197866775, COSV100982819; called by muse, varscan2
- PRKAA2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV64803832; called by muse, varscan2
- PRKAA2 | c.1248G>A p.M416I | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100982822; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2, varscan2
- PRLR | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV99184369; called by muse, mutect2, varscan2
- PRLR | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763133065, COSV99184381; called by muse, mutect2, varscan2
- PRSS58 | c.576+1G>A p.X192_splice | Splice Site (SNP) | VAF 19/78 reads (24%) | catalogued as rs1335781612, COSV101616127; called by muse, mutect2, varscan2
- PTPRD | c.4099G>A p.G1367S | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.225); catalogued as COSV100644732; called by muse, mutect2, varscan2
- PTPRF | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV100740871; called by muse, mutect2, varscan2
- PTPRK | c.4313C>T p.S1438L (on ENST00000368215 / NM_001291984.2; = p.S1439L on NM_002844.4) | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV63909600; called by muse, mutect2, varscan2
- PTPRK | c.2767G>A p.D923N (on ENST00000368215 / NM_001291984.2; = p.D924N on NM_002844.4) | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs902630929, COSV63893699; called by muse, mutect2, varscan2
- PUM1 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 48/88 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99928015; called by muse, mutect2
- PXDN | c.2812C>A p.Q938K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.034); catalogued as COSV99413382; called by muse, mutect2, varscan2
- PXDNL | c.1444G>A p.D482N | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.902); catalogued as rs757058225, COSV62485102; called by muse, mutect2, varscan2
- PYGM | c.2255C>T p.S752F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs571207448, COSV51216919, COSV51232225; called by muse, varscan2
- RAB38 | c.159G>A p.W53* | Nonsense Mutation (SNP) | VAF 54/112 reads (48%) | catalogued as COSV99703078; called by muse, mutect2
- RAD18 | c.596T>C p.V199A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV99368399; called by muse, mutect2, varscan2
- RALGAPA2 | c.1544T>C p.F515S | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV99173573; called by muse, mutect2, varscan2
- RALGAPB | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.989); catalogued as COSV53443917; called by muse, mutect2, varscan2
- RANBP2 | c.6187C>T p.L2063F | Missense Mutation (SNP) | VAF 115/294 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51706106; called by muse, mutect2, varscan2
- RANBP2 | c.7264C>T p.R2422C | Missense Mutation (SNP) | VAF 34/316 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs755911705, COSV51697236; called by mutect2, varscan2
- RASGRF1 | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.622); catalogued as COSV101369624; called by muse, varscan2
- RBM11 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.23); catalogued as COSV101271204, COSV68747971; called by muse, mutect2, varscan2
- RELN | c.9824C>T p.S3275F | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59033491; called by muse, mutect2, varscan2
- RESF1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.12); catalogued as COSV100440323; called by muse, mutect2, varscan2
- RESF1 | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV57025017; called by muse, mutect2, varscan2
- RGS22 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV100693217; called by muse, mutect2, varscan2
- RING1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1452547852, COSV100761752; called by muse, mutect2, varscan2
- RNMT | c.466C>T p.L156F | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100054618; called by muse, mutect2, varscan2
- ROBO2 | c.689G>A p.R230K | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as COSV100166530; called by muse, mutect2, varscan2
- RPS6KA1 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV100943080; called by muse, mutect2, varscan2
- RPS7 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV100513937; called by muse, mutect2, varscan2
- RRP15 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs566238943, COSV100860732; called by mutect2, varscan2
- RYR3 | c.8393C>T p.S2798F (on ENST00000389232; = p.S2799F on NM_001036.6) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.96); catalogued as rs776207635, COSV101212723; called by muse, mutect2, varscan2
- SART3 | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV57210169; called by muse, varscan2
- SCN11A | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56565290; called by muse, mutect2, varscan2
- SCN11A | c.4424G>A p.R1475K | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100181510; called by muse, mutect2, varscan2
- SCN11A | c.3082C>T p.P1028S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV56569171; called by muse, mutect2, varscan2
- SCN11A | c.1655C>T p.S552F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV100181511; called by muse, mutect2, varscan2
- SCN1A | c.4582-1G>A p.X1528_splice (on ENST00000303395 / NM_001202435.3; = p.X1517_splice on NM_006920.6 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 13/24 reads (54%) | catalogued as CS096244, COSV100319583, COSV100320333; called by muse, mutect2, varscan2
- SCN3A | c.5875G>A p.D1959N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV99326897; called by muse, mutect2, varscan2
- SCN3A | c.4550G>A p.G1517E | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99325710, COSV99326900; called by muse, mutect2, varscan2
- SCN3A | c.3118C>T p.H1040Y | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs776963443, COSV99326904; called by muse, mutect2, varscan2
- SCNN1B | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1334433731, COSV100225638, COSV100225754; called by muse, mutect2, varscan2
- SCTR | c.575A>G p.N192S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as rs374741128; called by muse, mutect2, varscan2
- SDR42E1 | c.1070G>A p.R357K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1274374252, COSV100200709; called by muse, mutect2, varscan2
- SEC14L5 | c.1159G>A p.G387R | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99228563; called by muse, mutect2, varscan2
- SELENOO | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV99955473; called by muse, mutect2, varscan2
- SEMA6A | c.2735A>T p.Y912F | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as COSV99145714; called by muse, mutect2, varscan2
- SERPINA3 | c.950C>T p.S317F | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV67587459; called by muse, mutect2, varscan2
- SEZ6L | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV50673638, COSV99962015; called by muse, mutect2, varscan2
- SGPP1 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV99905813; called by muse, mutect2, varscan2
- SGPP1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99905816; called by muse, mutect2, varscan2
- SGSM1 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV68514689; called by muse, mutect2, varscan2
- SI | c.3100-1G>A p.X1034_splice | Splice Site (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100015448, COSV52289771; called by muse, mutect2, varscan2
- SIGLEC6 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV100585364, COSV58432420; called by muse, mutect2, varscan2
- SIM1 | c.261C>T p.T87= | Splice Region (SNP) | VAF 14/45 reads (31%) | catalogued as rs755622030, COSV99492325; called by muse, mutect2, varscan2
- SLC12A5 | c.277A>T p.N93Y (on ENST00000454036 / NM_001134771.2; = p.N70Y on NM_020708.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV99715973; called by muse, mutect2, varscan2
- SLC12A5 | c.278A>C p.N93T (on ENST00000454036 / NM_001134771.2; = p.N70T on NM_020708.5) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV99715976; called by muse, mutect2, varscan2
- SLC14A1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 38/59 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0.104); catalogued as rs868527298, COSV58930983; called by muse, mutect2, varscan2
- SLC16A2 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs746493490, COSV99330639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A6 | c.1262G>A p.G421E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99581415; called by muse, mutect2, varscan2
- SLC25A12 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55534881, COSV99785001; called by muse, mutect2, varscan2
- SLC26A8 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs752023890, COSV62884793; called by muse, mutect2, varscan2
- SLC38A4 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759787871, COSV56966959; called by muse, mutect2, varscan2
- SLC5A1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV99833407; called by muse, mutect2, varscan2
- SLC6A18 | c.1620G>A p.W540* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as rs773388559; called by muse, mutect2, varscan2
- SLC7A2 | c.998G>A p.G333E (on ENST00000494857 / NM_001370338.1; = p.G373E on NM_003046.6) | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs1363232782, COSV50258762; called by muse, mutect2, varscan2
- SLC9A9 | c.1777G>T p.E593* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100340672; called by muse, mutect2, varscan2
- SLCO4C1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 27/43 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV100194925; called by muse, mutect2, varscan2
- SLFN11 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 24/35 reads (69%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as COSV100390615; called by muse, mutect2, varscan2
- SMPD3 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.08); catalogued as COSV99545633; called by muse, mutect2, varscan2
- SMTN | c.2119A>T p.K707* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as COSV100294304; called by muse, mutect2, varscan2
- SNAP91 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 47/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs201947130, COSV52122950; called by muse, mutect2, varscan2
- SNX29 | c.2329C>T p.P777S | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.968); catalogued as rs138093631, COSV100028529; called by muse, mutect2, varscan2
- SNX7 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 101/198 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as COSV100068934; called by muse, mutect2, varscan2
- SORL1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV99493749; called by muse, mutect2, varscan2
- SPEN | c.7742C>T p.P2581L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV101005214; called by muse, mutect2, varscan2
- SPTBN4 | c.2602G>A p.E868K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs566193157, COSV100150834; called by muse, mutect2, varscan2
- SRSF11 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV100917901, COSV100918051; called by muse, mutect2, varscan2
- SSMEM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99927708; called by muse, mutect2, varscan2
- ST8SIA4 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 22/53 reads (42%) | PolyPhen benign (0); catalogued as COSV99185257; called by muse, mutect2, varscan2
- STAC | c.975G>A p.G325= | Splice Region (SNP) | VAF 31/87 reads (36%) | catalogued as COSV56211068; called by muse, mutect2, varscan2
- STAG1 | c.616C>T p.L206F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52617316, COSV99365440; called by muse, mutect2, varscan2
- STARD13 | c.1078G>A p.G360R (on ENST00000336934 / NM_001243476.3; = p.G242R on NM_052851.3) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as rs756031221, COSV55233936; called by muse, mutect2
- STARD13 | c.625C>T p.R209C (on ENST00000336934 / NM_001243476.3; = p.R91C on NM_052851.3) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs768133626, COSV55234488; called by muse, mutect2, varscan2
- STAT1 | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV63117459; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2665G>A p.E889K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as COSV100561681; called by muse, mutect2, varscan2
- SUPT6H | c.3122C>T p.S1041F | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV58926556; called by muse, mutect2, varscan2
- SV2B | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as rs150480705, COSV57700429; called by muse, mutect2, varscan2
- SVOP | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100139385; called by muse, mutect2, varscan2
- SYNDIG1 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100965260; called by muse, mutect2, varscan2
- SYNM | c.4003G>A p.E1335K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100018719; called by muse, mutect2, varscan2
- TACC2 | c.5564G>A p.G1855E | Missense Mutation (SNP) | VAF 49/84 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs749273199, COSV57769520; called by muse, mutect2, varscan2
- TAF1L | c.3357G>A p.M1119I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as rs780537319, COSV99644498; called by muse, mutect2, varscan2
- TAF1L | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.586); catalogued as rs1284314192, COSV99644622; called by muse, varscan2
- TAF1L | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs765930570, COSV54256386; called by muse, varscan2
- TARS2 | c.553T>A p.C185S | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.2); catalogued as COSV100945970; called by muse, mutect2, varscan2
- TAS1R3 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as rs758845008, COSV100229511; called by muse, mutect2, varscan2
- TAS2R9 | c.626C>T p.T209I | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.329); catalogued as COSV53689849, COSV99553777; called by muse, mutect2, varscan2
- TBC1D9 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 33/52 reads (63%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV101464338; called by muse, mutect2, varscan2
- TCF19 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV99462965; called by muse, mutect2, varscan2
- TEKT1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs965142200, COSV100106180; called by muse, mutect2, varscan2
- TEKT1 | c.357G>A p.R119= | Splice Region (SNP) | VAF 12/28 reads (43%) | catalogued as COSV58622540; called by muse, mutect2, varscan2
- TENM1 | c.5527A>G p.I1843V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100949966; called by muse, mutect2, varscan2
- TENM4 | c.3262C>T p.L1088F | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99574288; called by muse, mutect2, varscan2
- TESPA1 | c.895C>T p.R299W (on ENST00000316577 / NM_001098815.3; = p.R161W on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs753442863, COSV100344787; called by muse, mutect2, varscan2
- TEX30 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as COSV101052015; called by muse, mutect2, varscan2
- TGIF2LX | c.721C>T p.P241S | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52213571, COSV99383312; called by muse, mutect2, varscan2
- THSD7B | c.4349G>A p.W1450* (on ENST00000272643; = p.W1448* on NM_001316349.2) | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV55715713; called by muse, mutect2, varscan2
- TIGD7 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV99239846; called by muse, mutect2, varscan2
- TIMELESS | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99973949; called by muse, mutect2, varscan2
- TMC6 | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1446801866, COSV100130087; called by muse, mutect2, varscan2
- TMCC2 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV100405273, COSV58001318; called by muse, mutect2, varscan2
- TMCO3 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754996138, COSV100952322; called by muse, mutect2, varscan2
- TMED2 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as COSV99147818; called by muse, mutect2, varscan2
- TMEM184B | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100725923, COSV100725969; called by muse, mutect2, varscan2
- TMPRSS11F | c.298C>T p.R100* | Nonsense Mutation (SNP) | VAF 62/113 reads (55%) | catalogued as rs542655796, COSV62464715; called by muse, mutect2, varscan2
- TNIK | c.3611G>T p.R1204I | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99454327, COSV99457099; called by muse, mutect2, varscan2
- TNR | c.2788G>A p.E930K | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.332); catalogued as rs531733667, COSV54868765; called by muse, mutect2, varscan2
- TNR | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV54874438; called by muse, mutect2, varscan2
- TNR | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54908133, COSV99689444; called by muse, mutect2, varscan2
- TNRC18 | c.4433C>T p.A1478V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV101269652; called by muse, mutect2, varscan2
- TOP2B | c.2112A>G p.Q704= (on ENST00000264331 / NM_001330700.2; = p.Q699= on NM_001068.3) | Splice Region (SNP) | VAF 37/121 reads (31%) | catalogued as rs1314965615, COSV99979662; called by muse, mutect2, varscan2
- TP53BP2 | c.425C>T p.S142F (on ENST00000343537 / NM_001031685.3; = p.S13F on NM_005426.2) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.768); catalogued as COSV59065953, COSV59067102; called by muse, mutect2, varscan2
- TP63 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV53207326; called by muse, varscan2
- TPO | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61102321; called by muse, mutect2, varscan2
- TPTE | c.1268C>T p.S423L (on ENST00000618007 / NM_199261.4; = p.S405L on NM_199259.4) | Missense Mutation (SNP) | VAF 64/504 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.739); catalogued as rs570468666; called by muse, varscan2
- TRAF6 | c.1139T>A p.F380Y | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777689; called by muse, mutect2, varscan2
- TRANK1 | c.7745C>T p.S2582F | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100081984, COSV100082805; called by muse, mutect2, varscan2
- TRANK1 | c.4574G>A p.G1525E | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100082811; called by muse, mutect2, varscan2
- TRAV8-2 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.065); catalogued as rs1300204718; called by muse, mutect2, varscan2
- TRERF1 | c.1884C>T p.L628= | Splice Region (SNP) | VAF 21/53 reads (40%) | catalogued as rs764898968, COSV61678928; called by muse, mutect2, varscan2
- TRIM27 | c.1100T>A p.I367N | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV101019323; called by muse, mutect2, varscan2
- TRIM27 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV101019325; called by muse, mutect2, varscan2
- TRIML2 | c.1187C>T p.S396F | Missense Mutation (SNP) | VAF 38/64 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as rs1373521206, COSV58717106, COSV58719474; called by muse, mutect2, varscan2
- TRPM5 | c.2512C>T p.L838F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as COSV99330070; called by muse, mutect2, varscan2
- TRPM5 | c.305G>A p.W102* | Nonsense Mutation (SNP) | VAF 48/80 reads (60%) | catalogued as COSV99330072; called by muse, mutect2, varscan2
- TRRAP | c.10753G>A p.E3585K (on ENST00000359863 / NM_001244580.1; = p.E3556K on NM_003496.3) | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as COSV62816642; called by muse, mutect2, varscan2
- TSGA10 | c.2059C>T p.R687* | Nonsense Mutation (SNP) | VAF 45/78 reads (58%) | catalogued as rs758007806, COSV61824185; called by muse, mutect2, varscan2
- TTBK2 | c.2353G>A p.E785K | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99141463; called by muse, mutect2, varscan2
- TTC25 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66369209; called by muse, mutect2, varscan2
- TTN | c.96664G>A p.E32222K (on ENST00000591111; = p.E24798K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | PolyPhen probably damaging (0.997); catalogued as COSV100611600; called by muse, mutect2, varscan2
- TTN | c.79508C>T p.S26503L (on ENST00000591111; = p.S19079L on NM_003319.4) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | PolyPhen benign (0.022); catalogued as COSV100611604; called by muse, mutect2, varscan2
- TTN | c.64684G>A p.G21562R (on ENST00000591111; = p.G14138R on NM_003319.4) | Missense Mutation (SNP) | VAF 4/40 reads (10%) | PolyPhen probably damaging (0.95); catalogued as COSV100611606; called by muse, mutect2
- TTN | c.59032G>A p.E19678K (on ENST00000591111; = p.E12254K on NM_003319.4) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | PolyPhen benign (0.298); catalogued as COSV100611608; called by muse, mutect2, varscan2
- TTN | c.53952G>A p.W17984* (on ENST00000591111; = p.W10560* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 28/84 reads (33%) | catalogued as COSV100611614; called by muse, mutect2, varscan2
- TTN | c.44744G>A p.G14915E (on ENST00000591111; = p.G7491E on NM_003319.4) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | PolyPhen probably damaging (1); catalogued as rs866384387, COSV60012244, COSV60238614; called by muse, mutect2, varscan2
- TTN | c.39412G>A p.E13138K (on ENST00000591111; = p.E5714K on NM_003319.4) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | PolyPhen probably damaging (0.994); catalogued as COSV60386201; called by muse, mutect2, varscan2
- TTN | c.36719G>A p.R12240Q (on ENST00000591111; = p.R4816Q on NM_003319.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | PolyPhen possibly damaging (0.873); catalogued as rs1268138413, COSV59911499; called by muse, mutect2, varscan2
- TTN | c.22919G>A p.G7640E (on ENST00000591111; = p.G6713E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | PolyPhen probably damaging (0.986); catalogued as COSV100611627; called by muse, mutect2, varscan2
- TTN | c.18830A>G p.K6277R (on ENST00000591111; = p.K5350R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | PolyPhen possibly damaging (0.732); catalogued as COSV100611629; called by muse, mutect2, varscan2
- TULP1 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753820059, COSV100004135; called by muse, mutect2, varscan2
- UBE2V2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101568636; called by muse, mutect2, varscan2
- UGP2 | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV100451601, COSV61429040; called by muse, mutect2, varscan2
- UNC5A | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs750460906, COSV99994501; called by muse, mutect2, varscan2
- URB2 | c.1477G>A p.G493S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.192); catalogued as COSV99271100; called by muse, mutect2, varscan2
- USH2A | c.11617C>T p.P3873S | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100234227; called by muse, mutect2, varscan2
- USH2A | c.8023C>G p.L2675V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as COSV56336357, COSV56436976; called by muse, mutect2, varscan2
- UVRAG | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1386810047, COSV100638349; called by muse, mutect2, varscan2
- VGLL2 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV100409915; called by muse, mutect2, varscan2
- VPS13D | c.11131C>G p.Q3711E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99166442; called by muse, mutect2, varscan2
- VWA3A | c.2276C>T p.P759L | Missense Mutation (SNP) | VAF 60/133 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55388708; called by muse, mutect2, varscan2
- VWA3B | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV101346027; called by muse, mutect2, varscan2
- WDR70 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99458720; called by muse, mutect2, varscan2
- WDTC1 | c.2027C>T p.P676L (on ENST00000319394 / NM_001276252.2; = p.P675L on NM_015023.5) | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV100088842; called by muse, mutect2, varscan2
- YIF1A | c.302A>G p.Y101C | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100268426; called by muse, mutect2, varscan2
- ZBTB1 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV62440060; called by muse, mutect2, varscan2
- ZBTB21 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); catalogued as COSV100177100; called by muse, mutect2, varscan2
- ZC2HC1A | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as COSV99804032; called by muse, mutect2, varscan2
- ZCCHC2 | c.2398C>T p.L800F | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99502394; called by muse, mutect2, varscan2
- ZCCHC8 | c.1976C>T p.P659L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100288649; called by muse, mutect2, varscan2
- ZDBF2 | c.4513C>T p.P1505S | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.234); catalogued as COSV65623450; called by muse, mutect2, varscan2
- ZFHX3 | c.6506C>T p.S2169F | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51735199; called by muse, mutect2, varscan2
- ZFHX4 | c.4285C>T p.L1429F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99262483; called by muse, mutect2, varscan2
- ZFPM2 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1478934899, COSV65872970; called by muse, mutect2, varscan2
- ZFYVE26 | c.4018C>T p.R1340C | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs752300050, COSV61328449, COSV61333019; called by muse, mutect2
- ZNF148 | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.057); catalogued as COSV100642050; called by muse, mutect2, varscan2
- ZNF180 | c.1726C>T p.P576S | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55421421; called by muse, mutect2, varscan2
- ZNF284 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.882); catalogued as rs776834810, COSV69690713; called by muse, mutect2, varscan2
- ZNF578 | c.1403C>T p.S468L | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV101405047, COSV69737241; called by muse, mutect2, varscan2
- ZNF611 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as rs751736531, COSV60539956, COSV60541477; called by muse, mutect2, varscan2
- ZNF655 | c.177G>T p.K59N | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV99402111; called by muse, mutect2
- ZNF787 | c.362C>T p.P121L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99555532; called by muse, mutect2, varscan2
- ZNF790 | c.1813G>T p.A605S | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as COSV100764819; called by muse, mutect2, varscan2
- ZNF804A | c.128A>C p.E43A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as COSV100167757; called by muse, mutect2, varscan2
- ZNF804A | c.1361C>T p.S454F | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs866013097, COSV56433687; called by muse, mutect2, varscan2
- ZNF81 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100095600; called by muse, mutect2, varscan2
- ZNF831 | c.3790C>T p.P1264S | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV100926001; called by muse, mutect2, varscan2
- ZP4 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as rs374676601; called by muse, mutect2, varscan2
- ZRANB3 | c.1206G>A p.Q402= | Splice Region (SNP) | VAF 12/58 reads (21%) | catalogued as rs1336880793, COSV99923544; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.696del p.R233Afs*10 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel*, varscan2
- AGK | c.476del p.S159Ifs*2 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- BICD2 | c.2167del p.T723Pfs*4 | Frame Shift Del (DEL) | VAF 20/40 reads (50%) | called by mutect2, pindel, varscan2
- CGNL1 | c.1067del p.L356* | Frame Shift Del (DEL) | VAF 32/67 reads (48%) | called by mutect2, pindel, varscan2
- CRTAC1 | c.1106_1108delinsCC p.R369Pfs*41 | Frame Shift Del (DEL) | VAF 37/82 reads (45%) | called by pindel, varscan2*
- DPYD | c.2767-2A>T p.X923_splice | Splice Site (SNP) | VAF 13/71 reads (18%) | called by muse, mutect2, varscan2
- FAM174A | c.546_548del p.L182del | In Frame Del (DEL) | VAF 49/89 reads (55%) | called by pindel, varscan2
- GPSM1 | c.2009G>A p.C670Y | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.056); called by muse, mutect2
- GPX5 | c.610_616del p.V204Qfs*10 | Frame Shift Del (DEL) | VAF 22/52 reads (42%) | called by mutect2, pindel, varscan2
- ITPRID1 | c.922_925del p.H308Cfs*5 | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel, varscan2
- KIF1A | c.107-1_107del p.X36_splice | Splice Site (DEL) | VAF 28/88 reads (32%) | called by muse*, mutect2, varscan2*
- KMT2B | c.2846_2847delinsA p.P949Hfs*37 | Frame Shift Del (DEL) | VAF 34/157 reads (22%) | called by pindel, varscan2*
- KNG1 | c.881del p.N294Tfs*11 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel, varscan2
- LCN15 | c.49del p.T17Rfs*75 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel*, varscan2
- OR2T35 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2
- PPP3CC | c.669_679dup p.L227Rfs*86 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | called by mutect2, varscan2
- PRAMEF7 | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 100/356 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PRAMEF8 | c.934C>T p.L312F | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SART3 | c.646del p.S216Lfs*6 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | called by pindel, varscan2
- AARS1 | c.2464C>T p.L822= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV99933474; called by muse, mutect2, varscan2
- ABCC12 | c.798G>A p.G266= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as COSV100252656; called by muse, mutect2, varscan2
- ABCD4 | c.1449C>T p.P483= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as rs747273884, COSV100084214; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCG2 | c.1485C>T p.F495= | Silent (SNP) | VAF 59/90 reads (66%) | catalogued as COSV99419200; called by muse, mutect2, varscan2
- ABRA | c.318G>A p.K106= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100357551, COSV61732577; called by mutect2, varscan2
- ACKR2 | c.966C>T p.Y322= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV99825514; called by muse, mutect2, varscan2
- ACKR2 | c.967C>T p.L323= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV99825515; called by muse, mutect2, varscan2
- ACSS3 | c.873A>G p.E291= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99698753; called by muse, mutect2, varscan2
- ADAMTS2 | c.1095C>T p.F365= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV99201964; called by muse, mutect2, varscan2
- ADAMTS3 | c.670C>T p.L224= | Silent (SNP) | VAF 21/30 reads (70%) | catalogued as COSV99711020; called by muse, mutect2, varscan2
- ADAMTS7 | c.3816G>A p.L1272= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as COSV101183096; called by muse, mutect2, varscan2
- ADAR | c.2541G>A p.L847= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99425957, COSV99426825; called by muse, mutect2
- ADCY10 | c.2331G>A p.E777= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as COSV100896835; called by muse, mutect2, varscan2
- ADGRA1 | c.1221C>T p.F407= | Silent (SNP) | VAF 8/9 reads (89%) | catalogued as rs771531450, COSV101192693; called by muse, varscan2
- ADGRB2 | c.4188C>T p.P1396= | Silent (SNP) | VAF 89/144 reads (62%) | catalogued as COSV99926184; called by muse, mutect2, varscan2
- ADGRF3 | c.3108C>T p.C1036= (on ENST00000311519 / NM_001145168.1; = p.C837= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/51 reads (59%) | catalogued as COSV100275018; called by muse, mutect2, varscan2
- ADGRG2 | c.2418T>A p.I806= (on ENST00000379869 / NM_001079858.3; = p.I803= on NM_005756.4) | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as COSV100492235; called by muse, mutect2, varscan2
- ADIPOR1 | c.750C>T p.I250= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV100579514; called by muse, mutect2, varscan2
- AGPAT3 | c.1035G>A p.V345= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1306289648, COSV99377415; called by muse, mutect2, varscan2
- AHSA1 | c.480C>T p.T160= | Silent (SNP) | VAF 20/83 reads (24%) | catalogued as COSV99375962; called by muse, mutect2, varscan2
- AKAP4 | c.2208C>T p.F736= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV100654254; called by muse, mutect2, varscan2
- AL592490.1 | c.657G>A p.P219= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101308186; called by muse, mutect2
- ALB | c.1671G>A p.V557= | Silent (SNP) | VAF 20/41 reads (49%) | catalogued as rs1381201686, COSV55738698; called by muse, mutect2, varscan2
- ALPK3 | c.1413C>T p.T471= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV99360853; called by muse, mutect2, varscan2
- ANK3 | c.7548C>T p.S2516= | Silent (SNP) | VAF 36/60 reads (60%) | catalogued as COSV99779805; called by muse, mutect2, varscan2
- ANKRD45 | c.534C>T p.V178= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV60961708; called by muse, mutect2, varscan2
- ANKRD45 | c.423C>T p.F141= | Silent (SNP) | VAF 21/81 reads (26%) | catalogued as COSV60962297; called by muse, mutect2, varscan2
- AOC1 | c.1023C>T p.F341= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs553084982, COSV62867172; called by muse, mutect2, varscan2
- APCS | c.669C>T p.V223= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99661311; called by muse, mutect2
- APRT | c.24G>A p.L8= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as COSV51938096; called by muse, mutect2, varscan2
- ARFGEF3 | c.3156C>T p.L1052= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1055537912, COSV99292817; called by muse, mutect2, varscan2
- ARHGAP29 | c.2622G>A p.L874= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV99558074; called by muse, mutect2, varscan2
- ARL2 | c.93C>T p.T31= | Silent (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99880581, COSV99880640; called by muse, mutect2, varscan2
- ARRDC5 | c.780C>T p.T260= (on ENST00000381781; = p.T246= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/29 reads (69%) | catalogued as COSV101108160; called by muse, mutect2, varscan2
- ATP2B4 | c.1539T>C p.A513= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100397473; called by muse, mutect2, varscan2
- ATRNL1 | c.3513G>A p.G1171= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV100370570; called by muse, mutect2, varscan2
- BAHCC1 | c.4452C>T p.G1484= | Silent (SNP) | VAF 104/167 reads (62%) | catalogued as COSV100311615; called by muse, mutect2, varscan2
- BAZ2A | c.2319G>A p.K773= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV99466069; called by muse, mutect2, varscan2
- BBOX1 | c.504G>A p.R168= | Silent (SNP) | VAF 5/68 reads (7%) | catalogued as COSV54193415; called by muse, mutect2
- BCKDHB | c.552C>T p.S184= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs1425607714, COSV100243556; called by muse, mutect2, varscan2
- BECN1 | c.1119G>A p.L373= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as COSV100162100; called by muse, mutect2, varscan2
- BIN1 | c.210C>T p.A70= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99387959; called by muse, mutect2, varscan2
- BLM | c.345G>A p.P115= | Silent (SNP) | VAF 8/93 reads (9%) | catalogued as rs374578971; called by muse, mutect2
- BMS1 | c.306C>T p.L102= | Silent (SNP) | VAF 69/111 reads (62%) | catalogued as rs371870243; called by muse, mutect2, varscan2
- BNIP5 | c.1902C>T p.F634= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs1369006917, COSV101465144; called by muse, mutect2, varscan2
- BPTF | c.7383C>T p.V2461= | Silent (SNP) | VAF 47/70 reads (67%) | catalogued as rs782112255, COSV100074886; called by muse, mutect2, varscan2
- C11orf65 | c.102C>T p.H34= | Silent (SNP) | VAF 48/117 reads (41%) | catalogued as rs1186023171, COSV101262803; called by muse, mutect2, varscan2
- C1orf94 | c.1779G>A p.G593= (on ENST00000488417 / NM_001134734.2; = p.G403= on NM_032884.5) | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV64913113; called by muse, mutect2, varscan2
- CABIN1 | c.3423C>T p.S1141= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV54078437; called by muse, mutect2, varscan2
- CACNA1E | c.792C>T p.P264= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV62386758, COSV62405104; called by muse, mutect2, varscan2
- CACNA2D3 | c.2215C>T p.L739= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV99873300; called by muse, mutect2, varscan2
- CADPS | c.2985C>T p.S995= | Silent (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99338007, COSV99338182; called by muse, mutect2, varscan2
- CADPS | c.1221C>T p.V407= | Silent (SNP) | VAF 24/72 reads (33%) | catalogued as COSV99338009; called by muse, mutect2, varscan2
- CARMIL1 | c.1134C>T p.S378= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100277730; called by muse, mutect2, varscan2
- CASP8 | c.1170G>A p.T390= (on ENST00000432109 / NM_033355.3; = p.T407= on NM_001228.4) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as rs539029508, COSV51855591; called by muse, mutect2, varscan2
- CASR | c.960C>T p.F320= | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs753011255, COSV56133741; ClinVar: likely benign; called by muse, mutect2, varscan2
- CATSPERB | c.2751G>A p.R917= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as rs1274950519, COSV99831244; called by muse, varscan2
- CAVIN2 | c.996C>T p.S332= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV100414161; called by muse, mutect2
- CCDC158 | c.1167G>A p.R389= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as rs1319044605, COSV66355412; called by muse, mutect2, varscan2
- CCDC170 | c.990C>T p.I330= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs377676781; called by muse, mutect2, varscan2
- CCR4 | c.921G>A p.L307= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV100447391; called by muse, mutect2, varscan2
- CD80 | c.306G>A p.V102= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as rs756974714, COSV99958248; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5082C>T p.S1694= | Silent (SNP) | VAF 27/43 reads (63%) | catalogued as COSV100575423; called by muse, mutect2, varscan2
- CECR2 | c.1269C>T p.P423= (on ENST00000342247 / NM_001290047.2; = p.P240= on NM_001290046.1) | Silent (SNP) | VAF 37/142 reads (26%) | catalogued as COSV99377851; called by muse, mutect2, varscan2
- CECR2 | c.4155C>T p.S1385= (on ENST00000342247 / NM_001290047.2; = p.S1201= on NM_001290046.1) | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs1264973861, COSV99377857; called by muse, mutect2, varscan2
- CELSR2 | c.3801C>T p.H1267= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as COSV99603757; called by muse, mutect2, varscan2
- CELSR2 | c.6891C>T p.A2297= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV99603761; called by muse, mutect2, varscan2
- CEP250 | c.6171G>A p.R2057= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100698916; called by muse, mutect2, varscan2
- CFAP61 | c.3429C>T p.F1143= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as COSV99844718; called by muse, mutect2, varscan2
- CHN1 | c.1179C>T p.T393= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99789178; called by muse, mutect2, varscan2
- CHRND | c.936C>T p.F312= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs755073623, COSV99285774; called by muse, mutect2, varscan2
- CKAP4 | c.993C>T p.L331= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100952448; called by muse, mutect2
- CLEC16A | c.2310G>A p.L770= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99901419; called by muse, mutect2, varscan2
- CLPTM1 | c.1044C>T p.A348= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as COSV100493763; called by muse, mutect2, varscan2
- CNGB1 | c.1578G>A p.K526= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2
- CNKSR3 | c.582A>C p.T194= | Silent (SNP) | VAF 37/112 reads (33%) | catalogued as COSV101401360; called by muse, mutect2, varscan2
329 further variants in this file (0 protein-altering or splice-affecting, 303 silent, 26 other) are not listed here.
